Somatic mutation profile of tumor specimen TCGA-ER-A19T-01A (aliquot TCGA-ER-A19T-01A-11D-A19A-08) from TCGA case TCGA-ER-A19T, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acral lentiginous melanoma, malignant; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 51.5 years (18,802 days).
Specimen TCGA-ER-A19T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20948a6b-54f7-4dea-bb52-7f784480ada7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A19T-10A (Blood Derived Normal), aliquot TCGA-ER-A19T-10A-01D-A19A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81bce608-c41e-481a-9125-f1387e6cc476

The open-access MAF lists 57 somatic variants for this specimen: 43 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 38, Silent 14, Nonsense Mutation 3, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IRF6 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1553248640, CM092310, COSV65418811; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS12 | c.4303-2A>T p.X1435_splice | Splice Site (SNP) | VAF 14/41 reads (34%) | catalogued as COSV61257738; called by muse, mutect2, varscan2
- AGMO | c.777T>A p.Y259* | Nonsense Mutation (SNP) | VAF 22/205 reads (11%) | catalogued as COSV61107993; called by muse, mutect2, varscan2
- ANKS6 | c.401G>C p.G134A | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62049376; called by muse, mutect2
- APOBEC3B | c.724-1G>A p.X242_splice | Splice Site (SNP) | VAF 21/136 reads (15%) | catalogued as COSV100213838; called by muse, mutect2, varscan2
- AURKAIP1 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 44/280 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.254); catalogued as COSV57938800; called by muse, mutect2, varscan2
- BCO1 | c.1367C>G p.A456G | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.576); catalogued as COSV50728436, COSV50730097; called by muse, mutect2, varscan2
- BRINP3 | c.748T>G p.Y250D | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66516399; called by muse, mutect2
- CCNB3 | c.2804A>G p.E935G | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV52070944, COSV99330034; called by muse, mutect2, varscan2
- DIS3 | c.755G>C p.R252T | Missense Mutation (SNP) | VAF 22/23 reads (96%) | SIFT tolerated (0.48); PolyPhen benign (0.039); catalogued as COSV66705859; called by muse, mutect2, varscan2
- DMXL1 | c.1111C>G p.L371V | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV60706730; called by muse, mutect2, varscan2
- DSG2 | c.1214G>C p.S405T | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.053); catalogued as COSV55197630; called by muse, mutect2, varscan2
- EPS8L1 | c.1610G>A p.G537E (on ENST00000201647 / NM_133180.3; = p.G410E on NM_017729.3) | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.058); catalogued as COSV52380607; called by muse, mutect2, varscan2
- GRIA1 | c.1792T>G p.F598V | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV53593378; called by muse, mutect2, varscan2
- HEMGN | c.518C>G p.S173C | Missense Mutation (SNP) | VAF 61/237 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV52325601; called by muse, mutect2, varscan2
- HIVEP1 | c.6848G>T p.R2283I | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.308); catalogued as COSV65099566; called by muse, mutect2, varscan2
- JMJD1C | c.3772A>G p.K1258E | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs750375034, COSV59513470; called by muse, mutect2, varscan2
- LILRA1 | c.1456C>G p.Q486E | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.298); catalogued as COSV52179060; called by muse, mutect2, varscan2
- MBD5 | c.3823A>C p.S1275R | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV68696136; called by muse, mutect2, varscan2
- MCCC2 | c.145A>G p.M49V | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.03); catalogued as COSV60153120; called by muse, mutect2, varscan2
- METTL27 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs139449951, COSV52895151; called by mutect2, varscan2
- MUC4 | c.2575G>C p.V859L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.101); catalogued as rs886823173, COSV62137321; called by muse, mutect2, varscan2
- MYC | c.328A>T p.M110L (on ENST00000377970; = p.M125L on NM_002467.6) | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.817); catalogued as COSV52369715; called by muse, mutect2, varscan2
- MYT1 | c.3184G>A p.G1062S | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs200181803, COSV100115351, COSV60502280; called by muse, mutect2
- NDUFAF2 | c.213G>A p.W71* | Nonsense Mutation (SNP) | VAF 107/212 reads (50%) | catalogued as COSV56937349; called by muse, mutect2, varscan2
- NLK | c.856G>C p.A286P | Missense Mutation (SNP) | VAF 38/334 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63490553; called by muse, mutect2, varscan2
- NLRP2 | c.1984C>A p.L662I | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as COSV54753138; called by muse, mutect2, varscan2
- ODF3 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs747210196, COSV57293180; called by muse, mutect2, varscan2
- OR4D2 | c.898A>G p.R300G | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs1212734814, COSV73459720; called by muse, mutect2, varscan2
- PGK2 | c.435T>A p.D145E | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs777833062, COSV59163183; called by muse, mutect2, varscan2
- PHC3 | c.2185C>T p.Q729* (on ENST00000494943 / NM_001308116.2; = p.Q741* on NM_024947.4) | Nonsense Mutation (SNP) | VAF 11/54 reads (20%) | catalogued as COSV71948463; called by muse, mutect2, varscan2
- PNMA3 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as rs146193731, COSV64721983; called by mutect2, varscan2
- POLR2I | c.54G>C p.Q18H | Missense Mutation (SNP) | VAF 42/187 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.876); catalogued as COSV52900059; called by muse, mutect2, varscan2
- POP1 | c.2794G>T p.A932S | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as COSV100856140, COSV62892142; called by muse, mutect2, varscan2
- RPS6KA4 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53701417; called by muse, mutect2, varscan2
- SCN8A | c.3521T>A p.V1174D | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV61977988; called by muse, mutect2
- SERPIND1 | c.1462C>G p.L488V | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.797); catalogued as COSV53137732; called by muse, mutect2, varscan2
- SLC8A1 | c.2695C>G p.Q899E | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1406498517, COSV60473963; called by muse, varscan2
- TIGAR | c.281T>C p.V94A | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.659); catalogued as COSV51627032; called by muse, mutect2, varscan2
- TMEM63A | c.421T>A p.S141T | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.158); catalogued as COSV64762631; called by muse, mutect2, varscan2
- ZNF154 | c.1109C>T p.S370F | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.598); catalogued as COSV70744835; called by muse, mutect2, varscan2
- ZNF473 | c.718C>G p.Q240E | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV54522359; called by muse, mutect2, varscan2
- OPLAH | c.1508T>C p.L503P | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CSK | c.843G>A p.R281= | Silent (SNP) | VAF 16/106 reads (15%) | catalogued as COSV54972952; called by muse, mutect2, varscan2
- EPG5 | c.5937C>T p.N1979= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as rs150214973; called by mutect2, varscan2
- FOXA2 | c.39C>T p.S13= (on ENST00000377115 / NM_153675.3; = p.S19= on NM_021784.5) | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV65795806; called by muse, mutect2, varscan2
- OR1M1 | c.276C>T p.I92= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV70036544; called by muse, varscan2
- OR1M1 | c.675C>T p.I225= | Silent (SNP) | VAF 28/167 reads (17%) | catalogued as COSV70036564; called by muse, varscan2
- OR1M1 | c.753C>T p.F251= | Silent (SNP) | VAF 31/231 reads (13%) | catalogued as COSV70036578, COSV70037567; called by muse, varscan2
- PCDHB4 | c.300G>A p.P100= | Silent (SNP) | VAF 26/101 reads (26%) | catalogued as COSV52020304; called by mutect2, varscan2
- PCDHGA7 | c.1890G>A p.R630= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as COSV53914344; called by muse, mutect2, varscan2
- QARS1 | c.1194C>T p.G398= | Silent (SNP) | VAF 38/126 reads (30%) | catalogued as rs200860200, COSV60274326; called by mutect2, varscan2
- RAD54L2 | c.2427C>T p.T809= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV56577528; called by muse, mutect2
- RUFY1 | c.2052C>A p.S684= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as COSV60158853; called by mutect2, varscan2
- SPDL1 | c.291A>G p.Q97= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as rs1034917383, COSV54667364; called by muse, mutect2, varscan2
- SPEG | c.8823C>T p.S2941= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV56665183; called by muse, mutect2, varscan2
- TMEM131 | c.2217C>T p.N739= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV51771749; called by muse, mutect2, varscan2
